Gene-level copy-number profile of tumor specimen HCM-SANG-0269-C18-01A-01D-A80T-32 from HCMI case HCM-SANG-0269-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: G2.
Specimen HCM-SANG-0269-C18-01A-01D-A80T-32: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d52ec7ce-7084-4c69-be20-94ec732d114d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0269-C18-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,710 have no estimate.
https://portal.gdc.cancer.gov/files/4160341b-ea97-459f-b2c9-45855303c0df

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 108; copy number 1: 560; copy number 2: 2,459; copy number 3: 21,825; copy number 4: 27,405; copy number 5: 4,017; copy number 6: 1,408; copy number 7: 34; copy number 8: 18; copy number 9: 602; copy number 10: 135; copy number 11: 342.

Homozygous deletions (total copy number 0; autosomes only): 108 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:21,950,406–22,552,156, 108 genes (within-gene range 0–1) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,079 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:114,314,482–114,337,626, 2 genes, copy number 9: CHAMP1, LINC01054.
- chr20:11,890,723–12,381,255, 5 genes, copy number 9: BTBD3, AL035448.1, AL109838.1, AL136460.1, PA2G4P2.
- chr20:17,222,851–60,034,011, 937 genes, copy number 9–11 (broad region; genes not listed).
- chr20:61,953,469–62,065,810, 1 gene, copy number 10 (within-gene range 8–10): TAF4.
- chr20:62,037,429–64,327,972, 134 genes, copy number 10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 453. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
